Surgical pathology report (de-identified scan), TCGA case TCGA-FL-A1YU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Hawaii - Normal Study, specimen TCGA-FL-A1YU-11A (Solid Tissue Normal).

[page 1 of 2]
Surgical Pathology Report

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Client: [REDACTED]
DOB: [REDACTED] Location: [REDACTED]
Gender: F
Physician(s): [REDACTED]
cc: [REDACTED]
Accession #: [REDACTED]
Taken: [REDACTED]
Received: [REDACTED]
Reported: [REDACTED]

History/Clinical Dx: Right adnexal mass

Postoperative Dx: (Not Provided)

*ICD-0-3 not applicable.
Normal path from non-cancer patient.*

Specimen(s) Received:

A: Left adnexa
B: Uterus, cervix, right ovary and tube, left parametrium

fw 11/1/11

DIAGNOSIS:

A. Left adnexa: Endometriosis with surface adhesions, left tube and ovary

B. Uterus, cervix, right tube and ovary:

Cervix:	Chronic inflammation
Endometrium:	Proliferative phase
Myometrium:	Leiomyoma, intramural
Right ovary:	Cystic follicles
Right tube:	Unremarkable

Intraoperative Consultation:

A. Frozen Section Interpretation: Benign

Gross Description

A. Received fresh labeled "left adnexa" is a previously opened single piece of soft tan to pink tissue, 38 grams, 9.0 x 7.0 x 1.0 cm. There is a tube, which measures 3.0 x 0.6 cm. The inner lining is smooth, and measures up to 0.7 cm in greatest thickness. There are areas of clotted blood within the cystic structure. Representative sections are submitted in six cassettes after frozen section, with cassette A1 as frozen section.

B. Received: In formalin are two pieces of soft tan to white tissue
Labeled: Left parametrium, right ovary, right fallopian tube, cervix, uterus
Weight: 85 grams
Size:
Uterus: 8.6 x 6.7 x 4.2 cm
Right ovary: 2.4 x 2.2 x 1.6 cm

Disclaimer Statement:

The information contained herein may be applicable to some of the procedures and/or tests used in the above report. This report was prepared by a pathologist who is not a physician. The TCGA has determined that this information is not necessary for the use of this report. This report is intended for clinical research use only. The TCGA is not responsible for any errors or omissions in this report. It should not be used for clinical decision making or for any other purpose.

[page 2 of 2]
Surgical Pathology Report

Appearance

Serosal surface:

Smooth, with jagged areas, subserosal bulging present

Cervix:

White, smooth, shiny, with no lesions grossly identified

Endometrium:

0.2 cm in thickness, tan, smooth with areas of mucoid material and clotted blood. There is a thickened area of endometrium on the posterior wall of the uterus, measuring up to 2.2 x 0.8 x 0.1 cm, 4.0 cm from the cervical margin. The surface is smooth, tan to white and firm, and does not appear to extend into the myometrium

Myometrium:

1.0 cm in thickness. Possible area of adenomyosis, 1.5 x 0.9 x 0.4 cm

Right tube and ovary:

Right tubes measures 4.9 x 0.4 x 0.4 cm, and shows evidence of tubal ligation. The ovary contains cystic structures, largest up to 0.9 x 0.9 x 0.6 cm, filled with clear serous fluid. There is one apparent myoma, up to 1.6 x 1.5 x 1.2 cm.

Other:

KEY TO CASSETTES:

1	-	Cervix
2	-	Lower uterine segment, full thickness
3-5	-	Endo/myometrium, full thickness with previously described tan nodule
6	-	Endo/myometrium
7	-	Possible area of adenomyosis
8	-	Right adnexa

Microscopic Description

A&B. The microscopic findings support the above diagnoses.

Source: NCI Genomic Data Commons file 650cab8d-9af4-4ca3-a2bb-fae69cbcfb3d (TCGA-FL-A1YU.50EB1015-2B54-4B28-B581-1F0707604595.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).